Gene-level copy-number profile of tumor specimen ALCH-B0BT-TTP1-A from ALCHEMIST case ALCH-B0BT, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 59.7 years (21,796 days).
Specimen ALCH-B0BT-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 98bd9014-6ae8-430f-a5c3-ce41794de4d3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B0BT-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/ace0864b-37d1-4e5d-8f41-c443f2e9c8c5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 47; copy number 1: 1,597; copy number 2: 49,360; copy number 3: 5,699; copy number 4: 1,542; copy number 5: 4; copy number 6: 34; copy number 7: 58; copy number 8: 1; copy number 9: 10; copy number 10: 7; copy number 12: 6; copy number 13: 1; copy number 15: 1; copy number 16: 27; copy number 17: 4.

Homozygous deletions (total copy number 0; autosomes only): 35 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:7,693,124–7,700,970, 3 genes (within-gene range 0–2): AL359881.3, AL359881.2, AL359881.1.
- chr1:12,716,110–12,728,760, 1 gene: AADACL3.
- chr1:12,791,397–12,831,410, 3 genes: PRAMEF1, LINC01784, PRAMEF11.
- chr1:12,926,162–12,928,253, 1 gene (within-gene range 0–2): PRAMEF29P.
- chr1:143,595,216–143,635,641, 2 genes: NBPF17P, PFN1P12.
- chr1:143,745,249–143,760,669, 1 gene: AC239800.1.
- chr2:89,234,174–89,254,015, 4 genes (within-gene range 0–2): IGKV2-29, IGKV2-30, IGKV3-31, IGKV1-32.
- chr9:61,665,579–61,666,386, 1 gene: AL935212.2.
- chr9:64,462,819–64,466,498, 2 genes: CR769776.2, CYP4F25P.
- chr11:72,685,075–72,693,808, 1 gene (within-gene range 0–2): ARAP1-AS1.
- chr12:51,186,936–51,217,708, 2 genes: POU6F1, AC139768.1.
- chr14:18,333,726–18,419,273, 4 genes: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr16:1,148,224–1,148,754, 1 gene: AC120498.8.
- chr16:81,106,533–81,106,639, 1 gene (within-gene range 0–2): RNU6-1191P.
- chr16:89,919,165–89,938,761, 3 genes (within-gene range 0–4): AC092143.1, AC092143.2, TUBB3.
- chr16:89,969,773–89,972,832, 1 gene (within-gene range 0–2): CENPBD1.
- chr17:22,331,597–22,332,410, 1 gene: AC087575.1.
- chr20:64,049,836–64,072,347, 2 genes: TCEA2, AL355803.1.
- chr22:18,150,170–18,177,397, 1 gene: USP18.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 153 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:101,696,850–102,452,565, 14 genes, copy number 6–10: MAP4K4, LINC01127, IL1R2, IL1R1, IL1R1-AS1, IL1RL2, FAM183DP, IL1RL1, IL18R1, SDR42E1P5, IL18RAP, MIR4772, AC007278.2, AC007278.1.
- chr2:103,109,759–106,345,433, 54 genes, copy number 7: AC073987.1, AC010881.1, CRLF3P1, AC018880.1, CAPZBP1, AC013727.1, AC013727.2, LINC01965, AC013727.3, AC096554.1, AHCYP3, AC068535.1, LINC01831, LINC01102, LINC01103, AC013402.2, AC013402.3, AC068057.3, AC013402.1, RPL23AP27, AC068057.1, AC068057.2, SNORA72, LINC01114, HMGB3P11, PANTR1, AC018730.1, POU3F3, LINC01159, AC010884.1, MRPS9-AS2, MRPS9, MRPS9-AS1, LINC01918, GPR45, AC012360.2, TGFBRAP1, AC012360.1, AC012360.3, C2orf49, FHL2, AC108058.1, NCK2, AC010978.1, AC009505.1, ECRG4, UXS1, AC018878.1, AC092106.1, RPL22P10, SRSF3P4, RPS21P2, RPL27AP4, ILRUNP1.
- chr3:96,566,357–96,777,683, 6 genes, copy number 12: AC107015.1, RNU6-1094P, MTRNR2L12, RPL18AP8, RCC2P5, CDV3P1.
- chr3:104,063,039–104,063,582, 1 gene, copy number 15: RAP1BP2.
- chr3:136,862,208–137,724,543, 7 genes, copy number 5–17: NCK1, RAD51AP1P1, IL20RB, IL20RB-AS1, RNA5SP142, AC117440.1, NPM1P17.
- chr3:137,998,735–139,006,268, 24 genes, copy number 6 (within-gene range 2–14): CLDN18, AC016252.1, DZIP1L, KRT8P36, A4GNT, AC023049.1, DBR1, ARMC8, NME9, MRAS, ESYT3, AC022497.1, CEP70, FAIM, PPIAP72, PIK3CB, GAPDHP39, RPL23AP40, EEF1A1P25, ATP5MC1P3, LINC01391, FOXL2, FOXL2NB, PRR23A.
- chr3:141,228,726–141,615,344, 11 genes, copy number 6–9: PXYLP1, AC022215.2, AC022215.1, AC117383.1, AC117383.2, ZBTB38, AC010184.1, KRT18P35, RASA2, RASA2-IT1, YWHAQP6.
- chr3:169,709,295–170,305,977, 27 genes, copy number 16: SDHDP3, RNU6-637P, TERC, Telomerase-vert, ACTRT3, AC078802.1, MYNN, AC078795.1, LRRC34, AC078795.3, AC078795.2, LRRIQ4, LRRC31, KRT18P43, SAMD7, AC008040.2, AC008040.1, AC008040.3, SEC62, SEC62-AS1, GPR160, RNU4-38P, KMT5AP3, PHC3, RNU6-315P, PRKCI, Y_RNA.
- chr6:32,517,353–32,530,287, 1 gene, copy number 8: HLA-DRB5.
- chr9:61,868,727–61,911,022, 3 genes, copy number 7: AL391987.3, Y_RNA, FAM242E.
- chr16:88,863,333–88,866,660, 1 gene, copy number 7: PABPN1L.
- chr19:797,075–812,327, 2 genes, copy number 9: PTBP1, MIR4745.
- chr19:1,107,637–1,174,268, 1 gene, copy number 5: SBNO2.
- chr19:1,275,530–1,279,244, 1 gene, copy number 13: FAM174C.

Autosomal genes at a single copy (total copy number 1): 1,110. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
